Somatic mutation profile of tumor specimen TCGA-AG-A00C-01A (aliquot TCGA-AG-A00C-01A-01D-A183-10) from TCGA case TCGA-AG-A00C, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 49.8 years (18,201 days).
Specimen TCGA-AG-A00C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c07a42e-c84a-4f15-a993-e367a63c7613.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A00C-10A (Blood Derived Normal), aliquot TCGA-AG-A00C-10A-01W-A00K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce3250d2-fe30-4252-b725-bbac9a754934

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 15, Silent 5, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 34/271 reads (13%) | catalogued as rs749943218; called by mutect2, varscan2
- ADAMTS16 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 134/364 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs752096825; called by muse, mutect2, varscan2
- CEP152 | c.5006C>T p.S1669L (on ENST00000380950 / NM_001194998.2; = p.S1613L on NM_014985.4) | Missense Mutation (SNP) | VAF 154/419 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as COSV57859412; called by muse, mutect2, varscan2
- FBXO43 | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 83/180 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71053898; called by muse, mutect2, varscan2
- HECTD1 | c.6481-2A>G p.X2161_splice | Splice Site (SNP) | VAF 150/227 reads (66%) | catalogued as COSV67946307; called by muse, mutect2, varscan2
- NPAS3 | c.1625C>T p.A542V (on ENST00000356141 / NM_001164749.2; = p.A510V on NM_022123.3) | Missense Mutation (SNP) | VAF 69/114 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.304); catalogued as rs1566556372, COSV100640552; called by muse, mutect2, varscan2
- PIK3CA | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as rs397517199, COSV104381248, COSV55880235, COSV55880477; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PML | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as rs1475848935, COSV51446379; called by muse, mutect2, varscan2
- RGS22 | c.3472A>C p.K1158Q | Missense Mutation (SNP) | VAF 114/410 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.153); catalogued as COSV62661606; called by muse, varscan2
- RPS2 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs1330678784; called by muse, mutect2, varscan2
- SFTPB | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV60893294; called by muse, varscan2
- TBC1D12 | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 173/489 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs377630453; called by muse, mutect2, varscan2
- ATXN7L3 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 267/770 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- DCAF12L2 | c.509A>C p.N170T | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- LRRIQ3 | c.854C>G p.A285G | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.196); called by muse, mutect2
- NCAM2 | c.1304G>T p.R435I | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PKNOX2 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 69/184 reads (38%) | called by muse, mutect2, varscan2
- RAB40A | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, varscan2
- ANKRD26 | c.5034C>T p.S1678= | Silent (SNP) | VAF 94/240 reads (39%) | catalogued as COSV65775483; called by muse, mutect2, varscan2
- COL7A1 | c.7458C>T p.P2486= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs766547317, COSV60390948; called by muse, mutect2, varscan2
- GPX6 | c.147C>T p.N49= | Silent (SNP) | VAF 206/572 reads (36%) | catalogued as rs767523979, COSV62657330, COSV62659016; called by muse, mutect2, varscan2
- NPHS1 | c.1845C>G p.R615= | Silent (SNP) | VAF 30/104 reads (29%) | called by muse, varscan2
- RAB40A | c.126G>A p.P42= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs748229696, COSV58491236; called by muse, varscan2
